Somatic mutation profile of tumor specimen 0DL4FP from CCDI case PBBJDE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Schwannoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.5 years (3,818 days).
Specimen 0DL4FP: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 47788fce-abd4-48da-afe6-a244948b1095.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DL4FN (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/de7dd0ec-0ddb-428b-a443-23902b65a385

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 3 silent.
By variant classification: Silent 3, Missense Mutation 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- UMOD | c.1492C>T p.R498* | Nonsense Mutation (SNP) | VAF 218/559 reads (39%) | catalogued as rs368993197; called by muse, mutect2, varscan2
- MAOA | c.1573C>T p.P525S | Missense Mutation (SNP) | VAF 300/388 reads (77%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TSPAN19 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 28/1181 reads (2%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); called by muse, mutect2
- SRSF4 | c.396T>C p.Y132= | Silent (SNP) | VAF 229/631 reads (36%) | catalogued as rs779179050; called by muse, mutect2, varscan2
- TSPAN19 | c.366T>C p.I122= | Silent (SNP) | VAF 28/1168 reads (2%) | catalogued as rs1267156464; called by muse, mutect2
- ZNF135 | c.810T>C p.Y270= (on ENST00000313434 / NM_001289401.2; = p.Y282= on NM_003436.4) | Silent (SNP) | VAF 140/336 reads (42%) | called by muse, mutect2, varscan2
